Surgical pathology report (de-identified scan), TCGA case TCGA-62-8395, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-8395-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, right, upper lobe: 13.0 x 10.0 x 6.0 cm

Tumor: diameter approx. 5.0 cm

Diagnosis:

Adenocarcinoma, mixed subtype (partially: acinar, papillary, solid, BAC)

Infiltration of pleura visceralis

Several tumor nodules in the same lobe

pT4, pN0 (0/24), pMx, G2

Supplementary examinations:

EGFR mutation analysis (sanger sequencing, Ex 18 – 21)

EGFR mutation negative

Note:

According to the actual TNM classification it would be pT3

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file d48883a9-73a3-4408-8275-65f0053ef8a6 (TCGA-62-8395.D30859B7-5AF5-4579-854B-BAB436E3AE9A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).